Somatic mutation profile of tumor specimen TARGET-10-PARABL-09A (aliquot TARGET-10-PARABL-09A-01D) from TARGET case TARGET-10-PARABL, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.0 years (2,187 days).
Specimen TARGET-10-PARABL-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d9c243f-4602-4e73-ad17-4598f5f53bff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARABL-10A (Blood Derived Normal), aliquot TARGET-10-PARABL-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/348979e6-23d8-4005-b051-2750dcb9794f

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, RNA 2, 5'UTR 1, In Frame Del 1, Silent 1, Splice Region 1, In Frame Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP2A1 | c.1166C>T p.A389V | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as rs1380703785; called by muse, mutect2, varscan2
- ASAH1 | c.1146G>A p.K382= | Splice Region (SNP) | VAF 6/82 reads (7%) | catalogued as COSV50501310; called by muse, mutect2
- DENND2A | c.2142C>G p.I714M | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV52049651; called by muse, mutect2
- H2BC1 | c.61G>A p.V21I | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs142382084; called by muse, mutect2, varscan2
- ISLR | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1292585718; called by muse, mutect2, varscan2
- PTPRS | c.4976G>A p.R1659H | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs749770933, COSV53619560; called by muse, mutect2, varscan2
- ACAD11 | c.1919_1921del p.V640del | In Frame Del (DEL) | VAF 17/102 reads (17%) | called by mutect2, pindel, varscan2
- FAT3 | c.6818T>A p.V2273D | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- MAMDC2 | c.2055G>C p.E685D | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT tolerated (0.09); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PCDH8 | c.1323_1324insCCCTATGAGCAG p.P441_A442insPYEQ | In Frame Ins (INS) | VAF 4/37 reads (11%) | called by mutect2, pindel
- RIPOR1 | c.64T>G p.S22A | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- SLCO1C1 | c.1011A>T p.E337D | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TRPC6 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KIF13A | c.1779T>C p.N593= | Silent (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2, varscan2
- AC018755.3 | n.216C>T | RNA (SNP) | VAF 11/40 reads (28%) | catalogued as rs748073309; called by muse, mutect2, varscan2
- AC053481.3 | n.380G>T | RNA (SNP) | VAF 28/119 reads (24%) | called by muse, mutect2, varscan2
- IGLV4-69 | chr22:22031472 ins G | 3'Flank (INS) | VAF 48/60 reads (80%) | called by mutect2, pindel*, varscan2*
- ZEB2 | c.-160del | 5'UTR (DEL) | VAF 14/44 reads (32%) | called by mutect2, pindel*, varscan2
